Surgical pathology report (de-identified scan), TCGA case TCGA-Q3-AA2A, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site University of Oklahoma HSC, specimen TCGA-Q3-AA2A-01A (Primary Tumor).

[page 1 of 4]
STATUS:

Obtained:

Subm Dr:

Received:

CLINICAL HISTORY:

PANCREATIC CANCER

SPECIMEN/PROCEDURE:

1. PANCREAS - WHIPPLE
2. LYMPH NODE - COMMON HEPATIC
3. JEJUNUM

ICD-O-3
Adenocarcinoma, duct NOS
8500/3
Site Pancreas head C25.0
J224/14

IMPRESSION:

- 1) HEAD OF PANCREAS, COMMON BILE DUCT AND DUODENUM, WHIPPLE RESECTION:
- . Invasive ductal adenocarcinoma, well differentiated, involving peripancreatic soft tissue (see tumor checklist).
- . Surgical margins of resection are negative, but close; tumor is within 1 mm of the retroperitoneal resection margin.
- . Negative for vascular space invasion.
- . Perineural invasion present.
- . Metastatic carcinoma involves nine of twenty-six lymph nodes (9/26).
- 2) LYMPH NODE, COMMON HEPATIC, BIOPSY:
- . One benign lymph node (0/1).
- 3) JEJUNUM, RESECTION:
- . Small intestinal mucosa with no significant histopathologic changes.

PANCREAS (EXOCRINE): RESECTION CASE SUMMARY

SPECIMEN

Head of pancreas
Duodenum
Common bile duct

PROCEDURE

Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy

TUMOR SITE

Pancreatic head

TUMOR SIZE

Greatest dimension: 3.5 x 3.0 x 1.7 cm

HISTOLOGIC TYPE

Ductal adenocarcinoma

HISTOLOGIC GRADE (DUCTAL CARCINOMA ONLY)

G1: Well differentiated

[page 2 of 4]
IMPRESSION: (continued)

MICROSCOPIC TUMOR EXTENSION

Tumor invades peripancreatic soft tissues

Tumor invades retroperitoneal soft tissue

MARGINS

Margins uninvolved by tumor

Distance of tumor from closest margin: <1 mm

Specify margin (if possible): Retroperitoneal

TREATMENT EFFECT (APPLICABLE TO CARCINOMAS TREATED WITH NEOADJUVANT THERAPY)

No prior treatment

LYMPH-VASCULAR INVASION

Not identified

PERINEURAL INVASION

Present

PATHOLOGIC STAGING (pTNM)

PRIMARY TUMOR (pT)

pT3: Tumor extends beyond the pancreas but without involvement of the celiac axis or the superior mesenteric artery

REGIONAL LYMPH NODES (pN)

pN1: Regional lymph node metastasis

Specify: Number of lymph nodes examined: 26

Number of lymph nodes involved: 9

DISTANT METASTASIS (pM)

Not applicable

ADDITIONAL PATHOLOGIC FINDINGS

Pancreatic intraepithelial neoplasia (highest grade): PanIN 1b

Chronic pancreatitis

ANCILLARY STUDIES

Not performed

CLINICAL HISTORY

None

Pathologic TNM (AJCC 7th Edition): pT3 N1

Dictated by:

Entered:

GROSS DESCRIPTION:

1 Received fresh, labeled with the patient's name and "Whipple" is a specimen consisting of duodenum(24 cm in length by 8 cm in open circumference by 0.6 cm wall thickness) and pancreatic head (3cm from the anterior to posterior, 6 cm in length and 3 cm from superior to inferior). There is a poorly defined white-tan mucinous tumor mass (3.5 x 1.7 x 3.0 cm) in the head of the pancreas which obstructs the main pancreatic duct. The bile duct is patent and measures 0.6 cm in diameter. The tumor is grossly 1.2 cm from the ampulla

** CONTINUED ON NEXT PAGE **

[page 3 of 4]
GROSS DESCRIPTION: (continued)

of Vater and does not grossly involve the duodenal muscularis mucosa. The tumor is 3.5 cm from the distal resection margin, which is grossly free of tumor. The anterior and posterior margins are composed of yellow adipose tissue measuring up to 0.5 cm in thickness and are grossly free of tumor. The remainder of the pancreatic parenchyma is firm, tan, and nodular. The cystic duct remnant measures 0.5 cm in length and 0.7 cm in diameter. The duodenal mucosa is unremarkable. Six probable lymph nodes are found in the posterior/inferior soft tissue ranging in size from 0.3 x 0.3 x 0.2 cm to 1.0 x 0.7 x 0.5 cm. Eight probable lymph nodes are found in the anterior/superior soft tissue, ranging in size from 0.5 x 0.5 x 0.3 cm to 1.0 x 0.7 x 0.7 cm. Three retroperitoneal probable lymph nodes are found, ranging in size from 0.7 x 0.8 x 0.5

Ink code: Blue-pancreatic resection margin, green-bile duct margin, orange-anterior and superior margin, yellow-posterior/inferior, black-retroperitoneal margin

CASSETTE SUMMARY:

CASSETTE 1A:	Bile duct margin
CASSETTE 1B:	Perpendicular section the retroperitoneal margin
CASSETTE 1C:	Pancreatic resection margin, perpendicular and serially sectioned
CASSETTE 1D:	Section showing relationship between ampulla of Vater and tumor
CASSETTE 1E:	Ampulla of Vater
CASSETTE 1G:	Bile duct and common pancreatic duct
CASSETTE 1H:	Tumor with relationship to retroperitoneal margin
CASSETTE 1J:	Tumor with relationship to the retroperitoneal margin
CASSETTE 1K:	Tumor with relationship to posterior margin
CASSETTE 1L:	Tumor with relationship to retroperitoneal and anterior margin
CASSETTE 1M:	Proximal duodenal margin
CASSETTE 1N-1P:	Distal duodenal margin, bisected
CASEETE 1Q:	Two posterior probable lymph nodes
CASSETTE 1R:	Four posterior probable lymph nodes
CASSETTE 1S:	One probable lymph node, bisected
CASSETTE 1T:	One probable lymph node, bisected
CASSETTE 1U:	Five anterior probable lymph nodes
CASSETTE 1V:	Three probable retroperitoneal lymph nodes
CASSETTE 1W:	One possible lymph node (anterior)
CASSETTE 1X:	Tumor with relationship to duodenal mucosa and retroperitoneal margin
CASSETTE 1Y:	One possible lymph node (anterior)
CASSETTE 1Z:	Three probable retroperitoneal lymph nodes

2. Received in formalin labeled "common hepatic lymph node" and with the patient's name. The specimen consists of a 2 x 0.8 x 0.8 cm pale tan lymph node. The specimen is serially sectioned and submitted entirely in one cassette.

3. Received in formalin labeled "jejunum" and with the patient's name. The specimen consists of a 30 cm in length by 1.5 cm in diameter unoriented portion of small bowel. The serosa is tan-pink and predominantly smooth. Opening the specimen reveals tan-pink, folded, grossly unremarkable mucosa. Sectioning reveals an average wall thickness of 0.1 cm. The specimen is representatively submitted as follows:

Cassette 3A-3B: Margins

Cassette 3C-3E: Representative sections of bowel

Dictated by: -

Entered:

** CONTINUED ON NEXT PAGE **

[page 4 of 4]
COPIES TO:

CPT Codes:

PANCREAS PART/TTL RESECTION/88309

ICD9 Codes:

157.9

Resident Physician:

I have personally reviewed the material
(specimen/slide) and approve this final report.

Electronically Signed by: _____

** END OF REPORT **

Source: NCI Genomic Data Commons file f1da72d0-cab7-4553-9050-f3a0e0563c26 (TCGA-Q3-AA2A.610503C8-F430-417D-803C-52B08510F38C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).